Somatic mutation profile of tumor specimen TCGA-KK-A8IK-01A (aliquot TCGA-KK-A8IK-01A-11D-A364-08) from TCGA case TCGA-KK-A8IK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.4 years (20,594 days).
Specimen TCGA-KK-A8IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5509b647-44e5-44a2-b9ff-48eb7702af17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IK-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IK-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec3c9711-fccd-45de-8635-0e6270aa0e40

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.787_789del p.Q263del | In Frame Del (DEL) | VAF 11/20 reads (55%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 29/51 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRA3 | c.3815T>C p.V1272A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99293222; called by muse, mutect2, varscan2
- CACNA1A | c.5984G>A p.R1995H | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1178337230, COSV100802298; called by muse, mutect2, varscan2
- CBL | c.2357C>G p.A786G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as COSV99876198; called by muse, mutect2, varscan2
- CDH22 | c.482T>G p.I161S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100952837; called by muse, mutect2, varscan2
- CPLX1 | c.191A>C p.Q64P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs774426352, COSV100408285; called by muse, varscan2
- EXT2 | c.785A>C p.H262P (on ENST00000343631; = p.H295P on NM_000401.3) | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV100640594; called by muse, mutect2, varscan2
- HOATZ | c.398C>A p.S133* (on ENST00000375618 / NM_001100388.1; = p.S160* on NM_207430.2) | Nonsense Mutation (SNP) | VAF 48/53 reads (91%) | catalogued as rs200623359, COSV100239453; called by muse, mutect2, varscan2
- ISM2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as rs1206687005, COSV99376615; called by muse, mutect2, varscan2
- MTG2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 131/344 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752099775, COSV63693387; called by muse, mutect2, varscan2
- MYC | c.932C>G p.A311G (on ENST00000377970; = p.A326G on NM_002467.6) | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99420268; called by muse, mutect2, varscan2
- MYG1 | c.216+2T>C p.X72_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99670415; called by muse, mutect2, varscan2
- NUTM2A | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.493); catalogued as rs772493488, COSV101095694; called by mutect2, varscan2
- PDE10A | c.1069T>A p.Y357N | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100605035; called by muse, mutect2, varscan2
- PHF2 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV100823129; called by muse, mutect2, varscan2
- RPRD2 | c.2855C>G p.T952S | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV100955047; called by muse, mutect2, varscan2
- TUT7 | c.2842dup p.Y948Lfs*2 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | catalogued as rs751076382; called by mutect2, varscan2
- ZIC1 | c.158C>A p.S53* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as rs1204298030, COSV51550495, COSV99291858; called by muse, mutect2, varscan2
- ZNF230 | c.859A>G p.K287E | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV101431992; called by muse, mutect2, varscan2
- ZNF398 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100246896; called by muse, mutect2, varscan2
- ANKRD30A | c.1801_1803del p.S601del (on ENST00000611781; = p.S545del on NM_052997.2) | In Frame Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- DEFB104B | c.55_56insT p.P19Lfs*7 | Frame Shift Ins (INS) | VAF 2/4 reads (50%) | called by mutect2, pindel*
- MAOA | c.1000del p.S334Qfs*2 | Frame Shift Del (DEL) | VAF 53/80 reads (66%) | called by mutect2, pindel, varscan2
- NUCB2 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.215); called by muse, mutect2
- ACHE | c.1668C>T p.R556= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99574045; called by muse, mutect2
- AFAP1 | c.1224G>A p.T408= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs557744197, COSV100631458; called by muse, mutect2, varscan2
- BLM | c.3447G>A p.L1149= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1195487968, COSV100757182; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHB2 | c.453C>T p.D151= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV101006941; called by muse, mutect2, varscan2
- FGF3 | c.339C>T p.A113= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1219364101, COSV100490182; called by muse, mutect2, varscan2
- PASD1 | c.540C>T p.L180= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100949321; called by muse, mutect2
- TCTN2 | c.516T>G p.P172= | Silent (SNP) | VAF 49/53 reads (92%) | catalogued as COSV100315204; called by muse, mutect2, varscan2
- TLR8 | c.2745T>G p.L915= (on ENST00000218032 / NM_138636.5; = p.L933= on NM_016610.4) | Silent (SNP) | VAF 59/62 reads (95%) | catalogued as COSV99486981; called by muse, mutect2, varscan2
- TMEM182 | c.586C>T p.L196= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV68425516; called by muse, mutect2, varscan2
- TNFRSF1A | c.576G>A p.T192= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs779458638, COSV50598605; called by muse, mutect2, varscan2
